Surgical pathology report (de-identified scan), TCGA case TCGA-19-A6J5, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-A6J5-01A (Primary Tumor).

[page 1 of 3]
PATIENT NAME: [REDACTED]

MED REC # [REDACTED]

DOB: [REDACTED]

ORDER DOCTOR: [REDACTED]

PATIENT TYPE: [REDACTED]

ROOM #: [REDACTED]

EXAM DATE: [REDACTED]

BILLING #: [REDACTED]

ICD-O-3

Glioblastoma multiforme

GCF

Site Brain NOS

path

C71.9

① Brain, supratentorial NOS

C71.0

SURGICAL PATHOLOGY INQUIRY

7/24/13

CASE: [REDACTED]

PATIENT: [REDACTED]

Clinical History: Bilateral tumor, right frontal craniotomy for resection tumor

Pre-Operative Diagnoses: None Given

Post-Operative Diagnosis: None Given

Specimen(s) Submitted: A. Right frontal brain tumor 2/s; B. Right frontal brain tumor s/p

CPT Code(s) 88307 X 2; 88333 X 1

FINAL DIAGNOSIS:

A. Right temporal lesion: Glioblastoma multiforme, WHO grade IV. See note.

B. Right temporal lesion: Glioblastoma multiforme, WHO grade IV. See note.

Note: The tumor consists of neoplastic astrocytes, with "naked" infiltrating nuclei and small cell GBM patterns seen (with typical microcalcifications). Tumor infiltrates cortex, with perineuronal satellitosis. Mitoses are numerous, pseudopalisading and regional necrosis are seen, but no definite vascular endothelial proliferation is identified. Tumor corresponds to a WHO grade IV. A tissue block will be sent for

BRAIN, Resection

MACROSCOPIC

Specimen Type

X Resection

Specimen Size

Greatest dimension: 9 x 5.9 x 3 cm

[page 2 of 3]
PATIENT NAME: [REDACTED]

BILLING #: [REDACTED]

MED REC #: [REDACTED]

DOB: [REDACTED]

ORDER DOCTOR:

PATIENT TYPE:

ROOM #: [REDACTED]

EXAM DATE:

SURGICAL PATHOLOGY INQUIRY

Tumor Site

☒ Cerebrum: right frontal

Tumor Size

☒ Cannot be determined

MICROSCOPIC

Histologic Type

☒ Glioblastoma

Histologic Grade

☒ WHO Grade IV

Intraoperative Consultation:

A. Right frontal tumor (SMA):

- Glioblastoma multiforme.

Gross Description:

This case has 2 parts, both received fresh and labeled with the patient's name, [REDACTED]

A. Labeled "right frontal brain tumor" is a 1.2 x 0.5 x 0.2 cm aggregate of gray-brown soft tissue, submitted in cassette [REDACTED] A1.

B. Labeled "right frontal brain tumor" is an 84.8 gram, 9 x 5.9 x 3 cm piece of gray-tan tissue consistent with brain cortex. The cut surface shows some normal brain architecture with good delineation between gray and white matter with the remaining tissue (10%) hemorrhagic, soft, gray-red with areas of yellow-orange discoloration. Representative sections (approximately 15% of specimen) are submitted in cassettes [REDACTED]

Microscopic Description:

11 H2

[page 3 of 3]
PATIENT NAME: [REDACTED]

MED REC #: [REDACTED]

DQB: [REDACTED]

ORDER DOCTOR: [REDACTED]

PATIENT TYPE: [REDACTED]

ROOM #: [REDACTED]

EXAM DATE: [REDACTED]

BILLING #: [REDACTED]

SURGICAL PATHOLOGY INQUIRY

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

The pathologist signing this report is located at [REDACTED]

Pathologist

Electronically signed: [REDACTED]

Source: NCI Genomic Data Commons file 0aaff02c-cfc5-4d2f-875b-bd31b6e1f909 (TCGA-19-A6J5.C90FBF2D-9022-4E19-8AB6-DD008E82F12B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).